MMRF case MMRF_2730 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ad99e7b0-9222-4c58-8dac-141eaf45ad46

Demographics
Sex at birth: male; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.7 years (21,060 days); ISS stage: III; Days to last known disease status: 30 days; Days to last follow up: 30 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -17, day 30.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 253 ×10⁹/L.
- Creatinine 102 µmol/L.
- Lactate Dehydrogenase 3.73 µkat/L.
- Hemoglobin 8.12 mmol/L.
- Calcium 2.6 mmol/L.
- Albumin 38.7 g/L.
- Beta 2 Microglobulin 27 µg/mL.
- M Protein 1.56 g/dL.
- Absolute Neutrophil 1.55 ×10⁹/L.

Other clinical attributes
- Day -17: Weight: 70 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2730_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2730_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
